Somatic mutation profile of tumor specimen TARGET-30-PALBFW-01A (aliquot TARGET-30-PALBFW-01A-01W) from TARGET case TARGET-30-PALBFW, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Medulla of adrenal gland; Age at diagnosis: 2.2 years (804 days).
Specimen TARGET-30-PALBFW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a109f625-f9e3-491a-af6f-453432d4275c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PALBFW-10A (Blood Derived Normal), aliquot TARGET-30-PALBFW-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7dc7dced-cd74-46c0-8c8c-c5d1c15345e8

The open-access MAF lists 17 somatic variants for this specimen: 16 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 14, Nonsense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHR | c.2526G>T p.L842F | Missense Mutation (SNP) | VAF 176/1050 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.646); catalogued as COSV54124240, COSV54126848; called by muse, mutect2, varscan2
- BICD1 | c.1690G>T p.A564S | Missense Mutation (SNP) | VAF 17/244 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.371); catalogued as COSV55682593; called by muse, mutect2
- CD19 | c.1069C>A p.P357T | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.342); catalogued as COSV100218100, COSV61188826; called by muse, mutect2, varscan2
- CFTR | c.2978A>G p.D993G | Missense Mutation (SNP) | VAF 62/958 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs777904861, CM074734; called by muse, mutect2
- GABRG3 | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 22/462 reads (5%) | catalogued as rs933412981, COSV61512316; called by muse, mutect2
- PNMA8B | c.1477G>T p.A493S | Missense Mutation (SNP) | VAF 14/233 reads (6%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.638); catalogued as COSV66535873; called by muse, mutect2
- PODXL | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 32/250 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as COSV59870854; called by muse, mutect2, varscan2
- PRSS12 | c.2402G>A p.R801Q | Missense Mutation (SNP) | VAF 212/768 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1033229181, COSV56607141; called by muse, mutect2
- SLC26A4 | c.2254T>C p.C752R | Missense Mutation (SNP) | VAF 40/287 reads (14%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.014); catalogued as COSV55917447; called by muse, mutect2, varscan2
- THBS2 | c.2039G>A p.C680Y | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64679653; called by muse, mutect2, varscan2
- FAM241A | c.161A>G p.E54G | Missense Mutation (SNP) | VAF 34/424 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2
- FRMD4B | c.3092G>A p.G1031E | Missense Mutation (SNP) | VAF 29/477 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- GSDMC | c.1507C>T p.Q503* | Nonsense Mutation (SNP) | VAF 35/1210 reads (3%) | called by muse, mutect2
- KRTAP5-3 | c.200G>T p.C67F | Missense Mutation (SNP) | VAF 25/384 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.785); called by muse, mutect2
- PCDHAC2 | c.2323C>A p.Q775K | Missense Mutation (SNP) | VAF 25/384 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.297); called by muse, mutect2
- ZNF689 | c.672G>T p.Q224H | Missense Mutation (SNP) | VAF 15/213 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- STOML1 | c.192C>T p.F64= | Silent (SNP) | VAF 9/246 reads (4%) | called by muse, mutect2
